Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3FR, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3FR-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name:	[Redacted]	Service:	[Redacted]	Accession #:	[Redacted]
MRN:	[Redacted]	Visit #:	[Redacted]	Collected:	[Redacted]
DOB:	[Redacted]	Location:	[Redacted]	Received:	[Redacted]
Gender:	[Redacted]	Facility:	[Redacted]	Reported:	[Redacted]
HCN:	[Redacted]				
Ordering MD:	[Redacted]				
Copy To:	[Redacted]				

Specimen(s) Received

1. Thyroid: total thyroid and central neck dissection. stitch mark left superior pole

Diagnosis

Multifocal papillary carcinoma, dominant 3.0 cm, classical variant, left; mild follicular nodular disease: Thyroid

Metastatic papillary thyroid carcinoma: Lymph nodes, 2 of 4, central compartment

No pathological diagnosis: Lymph nodes, 3, isthmus

No pathological diagnosis: Parathyroid, left perithyroidal

- Total thyroidectomy specimen with central neck dissection.

1CD-0-3

Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 lw
11/22/11

Synoptic Data

Procedure:	Total thyroidectomy with central compartment dissection
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	5.0 cm
	2.4 cm
	1.6 cm
	Left lobe:
	5.0 cm
	2.7 cm
	2.2 cm
	Isthmus +/- pyramidal lobe:
	4.5 cm
	1.4 cm
	0.6 cm
	Central compartment:
	3.0 cm
	2.0 cm
	0.5 cm
Specimen Weight:	23.2 g
Tumor Focality:	Multifocal, bilateral
	Multifocal, midline (isthmus)
----- DOMINANT TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 3.0cm

[page 2 of 3]
Surgical Pathology Consultation Report

Histologic Type: Additional dimension: 2.0 cm
Additional dimension: 1.9 cm
Papillary carcinoma, classical (usual)
Classical (papillary) architecture
Classical cytomorphology

Histologic Grade: Not applicable

Margins: Margins uninvolved by carcinoma

Tumor Capsule: Totally encapsulated

Tumor Capsular Invasion: Indeterminate

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Extrathyroidal Extension: Not identified

----- SECOND TUMOR -----

Tumor Laterality: Right lobe

Isthmus

Tumor Size: Greatest dimension: 0.7cm

Histologic Type: Papillary carcinoma, classical (usual)
Classical (papillary) architecture
Classical cytomorphology

Histologic Grade: Not applicable

Margins: Margins uninvolved by carcinoma
Distance of invasive carcinoma to closest margin: 0.4mm

Tumor Capsule: Partially encapsulated

Tumor Capsular Invasion: Present, extent widely invasive

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Extrathyroidal Extension: Not identified

TNM Descriptors: m (multiple primary tumors)

Primary Tumor (pT): pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid

Regional Lymph Nodes (pN): pN1a: Nodal metastases to Level VI (pretracheal, paratracheal and prelaryngeal/Delphian) lymph nodes
Number of regional lymph nodes examined: 7
Number of regional lymph nodes involved: 2
Lymph Node, Extranodal Extension Not identified

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: Adenomatoid nodule(s) or Nodular follicular disease
Thyroiditis, focal (nonspecific)
Thyroiditis, palpation
Parathyroid gland(s), within normal limits
Other: Additional papillary microcarcinoma identified (0.1cm) in the right lobe.

*Pathologic Staging is based on AJCC/UICC TNM,

Electronically verified by:

Gross Description

The specimen labeled with the patient's name and as "total thyroid and central neck dissection stitch marks left superior pole" consists of a thyroid gland that is oriented with a suture on the left superior pole and weighs 23.2 g. The right lobe measures 5.0 cm SI x 2.4 cm ML x 1.6 cm AP, the left lobe measures 5.0 cm SI x 2.7 cm ML x 2.2 cm AP and the isthmus measures 4.5 cm SI x 1.4 cm ML x 0.6 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or lymph nodes are identified grossly. The left lobe contains a single delineated nodule that measures 3.0 cm SI x 2.0 cm ML x 1.9 cm AP. At the interface of the right lobe and isthmus there is a second delineated nodule that measures 0.4-cm SI x 0.7-cm ML x 0.4 cm AP. The remainder of the thyroid tissue is grossly

[page 3 of 3]
Surgical Pathology Consultation Report

unremarkable. There is a section of mediastinal fat attached to the inferior excision margin of the isthmus that measures 3.0 cm SI x 2.0 cm ML x 0.5 cm AP. Sectioning of the fat reveals the presence of two tan nodes measuring 0.6 x 0.4 x 0.4 cm and 0.7 x 0.3 x 0.3 cm. Sections of the larger nodule in the left lobe and normal tissue from the right lobe are stored frozen. The remainder of the specimen is submitted as follows:

- 1A-I right lobe, superior to inferior with half of smaller nodule in blocks F and G
- 1J-M isthmus submitted in toto with remainder of small nodule in block J.
- 1N-U left lobe, superior to inferior
- 1V most superior lymph node
- 1W most inferior lymph node

Microscopic Description

The dominant tumor is an encapsulated 3.0 cm classical variant papillary carcinoma in the left lobe. The second dominant tumor (located in the isthmus and right lobe), though only 0.7 cm, shows a widely infiltrative pattern of growth with small disseminated tumor deposits in multiple regions in the isthmus and right lobe. Some of these tumor deposits are highly suspicious for lymphatic invasion. The second dominant tumor exhibits very focal tall cell changes (less than 5%). There is no evidence of vascular invasion.

Source: NCI Genomic Data Commons file f21f8915-8f38-4aca-9fb9-25bb797a4ebf (TCGA-EM-A3FR.604E6742-0F04-4E7C-8684-D29344ED6711.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).